Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A3QK, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A3QK-01B (Primary Tumor).

[page 1 of 5]
Results

SURGICAL PATHOLOGY (Order [REDACTED])

Patient Info

Patient Name [REDACTED]

Sex
Female

DOB [REDACTED]

Results

Spe [REDACTED] Redacted
Suk [REDACTED]
ICD-O-3
Carcinoma, urothelial, NOS
8120/3
Site: bladder, NOS
C67.9
7512.00

FINAL DIAGNOSIS

1. Right colon, segment of terminal ileum and appendix, colectomy (A) - Single focus of metastatic urothelial carcinoma present within subserosal lymphovascular space.
- Segment of colon with mild crypt architectural distortion and submucosal fibrosis, consistent with prior biopsy site changes; no evidence of residual dysplasia or adenocarcinoma.
- Hyperplastic polyp.
- Submucosal lipoma.
- Appendix and small bowel with no specific diagnostic alteration.
- Thirty-three pericolic lymph nodes, negative for carcinoma (0/33).
- See comment.
2. Right distal ureter, excision (B) - Benign portion of ureter, negative for urothelial dysplasia/carcinoma.
3. Left distal ureter, excision (C) - Benign portion of ureter, negative for urothelial dysplasia/carcinoma.
4. Urethral margin, excision (D) - Benign urethral tissue, negative for urothelial dysplasia/carcinoma.
5. Urinary bladder, uterus, cervix, and vagina, anterior exenteration
- Bladder with invasive high grade papillary urothelial carcinoma, extending through the perivesical fat and into the stroma of the endocervix and lower uterine segment myometrium, as well as into the vaginal submucosa (see comment).
- Lymphovascular invasion is identified.
- Perineural invasion is identified.
- Carcinoma extends to the inked posterior serosal surface of the bladder.
- Vaginal margin is negative for carcinoma.
- Ureteral and urethral margins are negative for carcinoma.
- Urothelial carcinoma in situ is identified in the bladder mucosa.
- Unremarkable uterine cervical mucosa.
- Inactive endometrium.
6. Urethral margin #2, excision (F) - Benign portion of urethra, negative for urothelial dysplasia/carcinoma.
7. Lymph nodes, right pelvic, excision (G) - Fourteen lymph nodes negative for carcinoma (0/14).
8. Lymph nodes, left pelvic, excision (H) - Metastatic urothelial

Diagnostic Discrepancy		
Prior Histology History		
Case is (clerical)		
Review Initial		

[page 2 of 5]
carcinoma involving five of twenty-three lymph nodes (5/23).
- Extranodal extension is identified.

COMMENT

1. (A) The entire previous biopsy site and colonic tissue adjacent to it were submitted for histologic evaluation. There is no evidence of residual dysplasia or invasive adenocarcinoma in this specimen. Slides from part A of this case were reviewed with Dr.

5. Procedure:
Anterior exenteration

Tumor Size (greatest dimension): 5.0 cm

Histologic Type:
Urothelial carcinoma

Associated Epithelial Lesions:
Urothelial carcinoma in situ

Histologic grade:
Urothelial Carcinoma (WHO):
High-grade

Microscopic Tumor Extension:
Perivesical fat
Myometrium
Endocervical stroma
Vaginal submucosa

Margins:
Margins uninvolved by invasive carcinoma. Carcinoma extends to the inked posterior serosal surface of the bladder.
Ureteral margins, urethral margin, and vaginal margin negative for carcinoma.

Lymphovascular Invasion :
Present

Pathologic Stage (TNM):

Number lymph nodes examined: 37
Number lymph nodes involved (any size): 5

Primary Tumor (pT)
pT4a

Regional Lymph Nodes (pN)
pN2

Distant Metastasis (pM):
pMX

Slides from the cystectomy specimen were reviewed at the
with Drs. and

[page 3 of 5]
[REDACTED], M.D.
(Electronic Signature)

SPECIMEN SUBMITTED

- A: RIGHT COLECTOMY
- B: RIGHT DISTAL URETER
- C: LEFT DISTAL URETER
- D: URETHRAL MARGIN
- E: BLADDER, UTERUS AND CERVIX
- F: URETHRAL MARGIN #2
- G: RIGHT PELVIC LYMPH NODES
- H: LEFT PELVIC LYMPH NODES

CLINICAL DATA

BLADDER CA

INTRAOPERATIVE CONSULT DIAGNOSIS

- B. Negative for carcinoma (Dr.).
- C. Mostly denuded epithelium, negative for carcinoma (Dr.
- D. Negative for carcinoma, however, no epithelium identified (Dr.
- F. Negative for carcinoma (Dr.

GROSS DESCRIPTION

A. Received fresh labeled "right colon" is a 14.5 cm segment of right colon with an attached 9 cm segment of terminal ileum. An appendix is identified. The serosal surface is smooth and glistening. The wall of the colon averages 0.3 cm in thickness. The wall of the terminal ileum averages 0.2 cm in thickness. The mucosa of the colon demonstrates a brown-yellow submucosal nodule measuring 1.3 x 1.3 cm located 5.4 cm from the distal margin. Sectioning reveals a yellow homogenous cut surface. It does not invade the underlying wall. Multiple soft white polyps are identified ranging in size from 0.1 to 0.4 cm. All appear superficial. In the ascending colon, there is an irregular red slightly depressed area resembling a possible biopsy site measuring 0.8 x 0.2 cm located 14 cm from the distal margin. It is superficial and does not invade into the underlying wall. The remaining mucosa is unremarkable. No firm mass lesions are identified. The mucosa of the terminal ileum is unremarkable. The attached appendix measures 4.7 cm in length and 0.9 cm in diameter. The lumen is dilated to 0.2 cm and contains fecal material. No perforations or ulcerations are seen. Sectioning through the surrounding fibroadipose tissue reveals multiple ovoid tan firm nodules resembling lymph nodes. Representative sections are submitted as follows: A1 margins (proximal margin blue, distal margin orange), A2-A3 submucosal nodule totally submitted, A3 biopsy site totally submitted, A4-A5 polyps totally submitted, A6 appendix, A7 ileocecal valve, A8 small bowel, A9-A17 lymph nodes.

B. Received fresh at the frozen desk labeled "right distal ureter" is a 0.3 cm in diameter, 0.2 cm in length luminal tan-pink soft tissue fragment. The specimen is totally submitted for frozen section in one cassette labeled B1.

[page 4 of 5]
C. Received fresh at the frozen desk labeled "left distal ureter" is a 0.3 cm in diameter, 0.2 cm in length tan-pink luminal soft tissue fragment. The specimen is totally submitted for frozen section in one cassette labeled C1.

D. Received fresh at the frozen desk labeled "urethral margin" is a 2 x 0.6 x 0.3 cm red-tan mucosal lined soft tissue fragment. The specimen is totally submitted for frozen section in one cassette labeled D1.

E. Received in formalin is a specimen consisting of a urinary bladder, bilateral ureters, uterus, attached cervix, and portion of vagina. The bladder measures 6.0 x 4.5 x 4.2 cm. The external surface of the bladder is covered by a smooth serosal lining at the dome and fibroadipose tissue at the remaining portion. After the bladder is opened, a tan fungating mass is identified in the right anterior bladder wall extending to the left and right trigone region measuring 5.0 x 3.1 x 1.2 cm. Upon multiple cross sections there does appear to be gross extension beyond the bladder wall extending to within 0.2 cm of the soft tissue margin. Also, identified on the left bladder wall is an ulcerated indurated area of mucosa measuring 4.2 x 3.0 cm. This area of this bladder wall extends posteriorly and is associated with a thickened bladder wall measuring up to 2.0 cm. The bladder wall grossly appears to be involved by a mass which extends beyond the bladder wall, approaching the soft tissue margin. The right ureter measures 5.0 cm and is unremarkable. The left ureter measures 6.0 cm and is also unremarkable. The uterus measures 6.0 x 3.5 x 3.5 cm, and weighs 53.2 grams. A section of vaginal cuff and vagina are present measuring 5.0 x 1.2 cm. The vaginal mucosa is unremarkable. The ectocervix is unremarkable. The endocervical canal measures 1.8 cm in length. Polyps are not present. The endometrial canal measures 4.2 cm in length and 2.0 cm in greatest width. The endometrium measures 0.1 cm in thickness and has a tan, smooth and glistening appearance. The myometrium measures 1.5 cm in thickness and is unremarkable. Representative sections are submitted as follows: E1 - additional section right ureter, E2 additional section left ureter, E3 posterior bladder wall with right ureter orifice and small portion of possible mass, E4-E7 right bladder wall with mass with extension beyond bladder wall with soft tissue margin, E8 anterior bladder wall, E9 left bladder wall with mass near ureter, E10-E12 left bladder wall with mass and soft tissue margin, E13 left trigone region with mass, E14 left trigone region with mass and portion of vaginal mucosa, E15 right trigone region with mass, E16 anterior bladder wall, E17-E18 posterior bladder wall with mass, E19-E20 anterior cervix, E21 posterior cervix, E22 anterior uterine wall, E23 posterior uterine wall.

F. Received fresh at the frozen desk labeled "urethral margin #2" are two fragments of red-pink soft tissue measuring 1.1 x 0.6 x 0.5 cm. The specimen is totally submitted for frozen section in one cassette labeled F1.

G. Received in formalin labeled "right pelvic lymph nodes" are multiple yellow-tan segments of nodular adipose tissue aggregating to 5.8 x 4.3 x 1.7 cm. Palpation reveals three tan, firm nodules resembling lymph nodes ranging in size from 1.2 to 1.8 cm in greatest dimension. Additionally a fragmented matted segment of nodular tissue is present measuring 4.4 x 4.0

[page 5 of 5]
cm. The nodules are totally submitted as follows: G1 two nodules, G2 one nodule bisected, totally submitted, G3-G7 fragmented matted segment totally submitted.

H. Received in formalin labeled "left pelvic lymph nodes" are multiple yellow-tan segments of nodular adipose tissue aggregating to 7 x 5 x 1.5 cm. Palpation reveals 14 tan, firm nodules resembling lymph nodes ranging in size from 0.2 to 2.4 cm in greatest dimension. Additionally one fragmented matted segment is also received in the same container measuring 5.5 x 2.0 cm. The nodules are totally submitted as follows: H1 four nodules, H2 four nodules, H3 four nodules, H4 one nodule, H5 one nodule, H6-H10 fragmented matted segment sectioned and totally submitted.

Patient ID #: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Date of Report: [REDACTED]
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Submitted by: [REDACTED]
Additional Physician(s): [REDACTED]

Location: [REDACTED]

Test performed by: [REDACTED]

Lab and Collection

SURGICAL PATHOLOGY (Order # [REDACTED] on [REDACTED] - Lab and Collection Information

Result History

SURGICAL PATHOLOGY (Order # [REDACTED] - Order Result History Report.

Result Information

Result Date and Time
[REDACTED]

Status
Final result

Provider Status
Reviewed

MyChart Status:

This result is currently not released to

[Display Full Result Report](#)

[Display Order Report](#)

Source: NCI Genomic Data Commons file 6e3a3e1d-2e9d-4d29-8603-d927cb615861 (TCGA-GV-A3QK.C6248F9C-58D2-4F68-9D45-B38F38DCCA53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).